Somatic mutation profile of tumor specimen ALCH-B36I-TTP1-A (aliquot ALCH-B36I-TTP1-A-1-0-D-A78R-36) from ALCHEMIST case ALCH-B36I, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 75.7 years (27,639 days).
Specimen ALCH-B36I-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 962e7165-6416-4dbc-bcd1-9707fd231c65.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B36I-NB1-A (Blood Derived Normal), aliquot ALCH-B36I-NB1-A-1-0-D-A78R-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/636524a8-e90d-4c38-b7e0-5c45005b885e

The open-access MAF lists 16 somatic variants for this specimen: 12 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 2, Nonsense Mutation 2, 3'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLG | c.10876C>A p.H3626N | Missense Mutation (SNP) | VAF 63/858 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as COSV64238357; called by muse, mutect2
- OR52N5 | c.419G>C p.R140P | Missense Mutation (SNP) | VAF 20/313 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); catalogued as rs144845456, COSV57699390; called by muse, mutect2
- PKP2 | c.1415C>T p.P472L | Missense Mutation (SNP) | VAF 35/239 reads (15%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as rs758950276; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- RENBP | c.960G>C p.M320I | Missense Mutation (SNP) | VAF 14/170 reads (8%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV64170297; called by muse, mutect2
- SIX5 | c.1984G>A p.V662M | Missense Mutation (SNP) | VAF 32/378 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.075); catalogued as rs758153599; called by muse, mutect2
- AMOTL1 | c.2357C>G p.S786C | Missense Mutation (SNP) | VAF 54/949 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.127); called by muse, mutect2
- CLPP | c.598A>T p.K200* | Nonsense Mutation (SNP) | VAF 12/232 reads (5%) | called by muse, mutect2
- DMC1 | c.25G>T p.E9* | Nonsense Mutation (SNP) | VAF 40/1002 reads (4%) | called by muse, mutect2
- MAN2A2 | c.2899G>T p.D967Y | Missense Mutation (SNP) | VAF 9/164 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PCDH1 | c.545A>T p.N182I | Missense Mutation (SNP) | VAF 24/375 reads (6%) | SIFT tolerated (0.4); PolyPhen benign (0.009); called by muse, mutect2
- TAF1D | c.14G>A p.G5E | Missense Mutation (SNP) | VAF 22/452 reads (5%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.022); called by muse, mutect2
- TLR5 | c.893G>A p.G298E | Missense Mutation (SNP) | VAF 30/870 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- GNS | c.1185C>T p.S395= | Silent (SNP) | VAF 443/1110 reads (40%) | called by muse, mutect2, varscan2
- SYN1 | c.1260G>A p.R420= | Silent (SNP) | VAF 8/177 reads (5%) | called by muse, mutect2
- KIF5A | c.3021-25G>A | Intron (SNP) | VAF 104/712 reads (15%) | called by muse, varscan2
- ZNF800 | c.*3A>G | 3'UTR (SNP) | VAF 10/200 reads (5%) | called by muse, mutect2
